Somatic mutation profile of tumor specimen ALCH-B1PK-TTP1-A (aliquot ALCH-B1PK-TTP1-A-1-0-D-A76C-36) from ALCHEMIST case ALCH-B1PK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.3 years (24,223 days).
Specimen ALCH-B1PK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3304d2d0-c343-4b7f-8c46-ff52dc69a4c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1PK-NB1-A (Blood Derived Normal), aliquot ALCH-B1PK-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f449c9ee-f7b7-4849-a980-d474515db43a

The open-access MAF lists 525 somatic variants for this specimen: 359 protein-altering or splice-affecting, 94 silent, 72 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 301, Silent 94, Intron 35, Nonsense Mutation 23, RNA 22, Frame Shift Del 15, Splice Site 13, 5'UTR 6, 5'Flank 5, 3'UTR 3, Frame Shift Ins 2, Translation Start Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 68/364 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OSGEP | c.530G>C p.G177A | Missense Mutation (SNP) | VAF 30/356 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as rs778931753; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 75/236 reads (32%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ABLIM1 | c.386G>T p.G129V | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs778293158; called by muse, varscan2
- ADAM23 | c.1726G>T p.D576Y | Missense Mutation (SNP) | VAF 36/197 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52228193; called by muse, mutect2, varscan2
- ADAMTS12 | c.4424G>C p.W1475S | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100710361; called by muse, mutect2, varscan2
- ADCY1 | c.1249G>C p.D417H | Missense Mutation (SNP) | VAF 113/695 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52031045; called by muse, mutect2, varscan2
- ADGRL3 | c.1001C>A p.A334E (on ENST00000506720 / NM_001322402.2; = p.A266E on NM_015236.6) | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101547447; called by muse, mutect2, varscan2
- AHNAK2 | c.11432C>T p.P3811L | Missense Mutation (SNP) | VAF 148/630 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1276473304; called by muse, varscan2
- AKAP6 | c.3764G>A p.S1255N | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs780694878; called by muse, mutect2, varscan2
- ALX4 | c.323A>T p.Q108L | Missense Mutation (SNP) | VAF 47/302 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV61327964; called by muse, mutect2, varscan2
- AP002512.3 | c.989G>T p.R330L | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as rs769272386, COSV54406138; called by muse, mutect2, varscan2
- APOB | c.4318G>A p.V1440I | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as rs530601244, COSV51929161; called by muse, mutect2, varscan2
- ARL13B | c.787G>T p.V263L (on ENST00000394222 / NM_001174150.2; = p.V156L on NM_144996.4) | Missense Mutation (SNP) | VAF 67/367 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.257); catalogued as COSV100116040; called by muse, mutect2, varscan2
- BRINP2 | c.261G>T p.R87S | Missense Mutation (SNP) | VAF 73/209 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.422); catalogued as COSV64175415; called by muse, mutect2, varscan2
- C3 | c.1003G>T p.G335C | Missense Mutation (SNP) | VAF 42/504 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55580655; called by muse, mutect2
- CACNA1E | c.6239G>T p.G2080V (on ENST00000367573 / NM_001205293.3; = p.G2037V on NM_000721.4) | Missense Mutation (SNP) | VAF 66/224 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.622); catalogued as COSV62387958; called by muse, mutect2, varscan2
- CACNA2D1 | c.1085C>A p.T362K | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100667642; called by muse, mutect2, varscan2
- CCDC112 | c.1331G>T p.R444I | Missense Mutation (SNP) | VAF 62/268 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.022); catalogued as COSV65472981; called by muse, mutect2, varscan2
- CD109 | c.2662A>G p.T888A | Missense Mutation (SNP) | VAF 51/204 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs754326353; called by muse, mutect2, varscan2
- CDH23 | c.7844C>G p.P2615R | Missense Mutation (SNP) | VAF 68/341 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs545934398; called by muse, mutect2, varscan2
- CES3 | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 26/262 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.581); catalogued as rs760003959; called by muse, mutect2, varscan2
- COBL | c.3090G>T p.Q1030H | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.459); catalogued as COSV99472754; called by muse, mutect2, varscan2
- COL14A1 | c.4411G>T p.G1471* | Nonsense Mutation (SNP) | VAF 36/234 reads (15%) | catalogued as COSV52868164; called by muse, varscan2
- COL7A1 | c.8428G>A p.A2810T | Missense Mutation (SNP) | VAF 118/784 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs143995717; called by muse, mutect2, varscan2
- CSMD1 | c.2179G>T p.G727C (on ENST00000520002; = p.G726C on NM_033225.6) | Missense Mutation (SNP) | VAF 45/535 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59306271; called by muse, mutect2
- CUTA | c.439G>A p.E147K (on ENST00000488034 / NM_001014840.2; = p.E124K on NM_015921.3) | Missense Mutation (SNP) | VAF 15/293 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755286224; called by muse, mutect2
- CYP11B2 | c.1342C>A p.R448S | Missense Mutation (SNP) | VAF 127/632 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59995677; called by muse, mutect2, varscan2
- DENND2A | c.2362C>A p.L788M | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); catalogued as COSV99327012; called by muse, mutect2, varscan2
- DENND5B | c.29C>G p.P10R | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); catalogued as rs1424482197; called by muse, mutect2, varscan2
- DISP3 | c.1198C>A p.L400M | Missense Mutation (SNP) | VAF 39/395 reads (10%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.938); catalogued as COSV53821037, COSV53834239; called by muse, mutect2
- DLG4 | c.1757G>T p.R586L (on ENST00000399506 / NM_001321075.3; = p.R629L on NM_001365.4) | Missense Mutation (SNP) | VAF 34/368 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV57238316; called by muse, mutect2
- DLGAP1 | c.2495G>T p.R832L | Missense Mutation (SNP) | VAF 40/256 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.559); catalogued as COSV100234843; called by muse, mutect2, varscan2
- DSCC1 | c.112G>C p.A38P | Missense Mutation (SNP) | VAF 94/445 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.301); catalogued as rs1313462162; called by muse, mutect2, varscan2
- ENGASE | c.1090G>T p.G364C | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374695310; called by muse, mutect2, varscan2
- FAM47B | c.433C>G p.L145V | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV61454676; called by muse, mutect2, varscan2
- FBLN2 | c.1054G>A p.G352R | Missense Mutation (SNP) | VAF 109/510 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.178); catalogued as rs978185780, COSV55480953; called by muse, mutect2, varscan2
- FBN2 | c.3530C>A p.T1177N | Missense Mutation (SNP) | VAF 144/883 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs1195359208; called by muse, mutect2, varscan2
- FFAR1 | c.415G>C p.G139R | Missense Mutation (SNP) | VAF 58/662 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV99323669; called by muse, mutect2
- GABRG1 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV54953928; called by muse, mutect2, varscan2
- GIMAP4 | c.91T>A p.L31M | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs113262562; called by muse, mutect2, varscan2
- GJA3 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1374010909; called by muse, mutect2, varscan2
- GNAS | c.179C>A p.P60H | Missense Mutation (SNP) | VAF 86/394 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.839); catalogued as COSV58344632; called by muse, mutect2, varscan2
- GREB1 | c.1448C>A p.P483Q | Missense Mutation (SNP) | VAF 76/439 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV99303318; called by muse, mutect2, varscan2
- GRIN2B | c.3826G>A p.A1276T | Missense Mutation (SNP) | VAF 87/396 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs564596433; called by muse, mutect2, varscan2
- HGF | c.781C>A p.R261S | Missense Mutation (SNP) | VAF 34/333 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); catalogued as COSV55950085, COSV55950987; called by muse, mutect2, varscan2
- HHATL | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.912); catalogued as rs568465929, COSV100124551; called by muse, mutect2, varscan2
- HOXD10 | c.509C>A p.P170H | Missense Mutation (SNP) | VAF 60/278 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV99982907; called by muse, mutect2, varscan2
- KRT6A | c.1424G>T p.R475M | Missense Mutation (SNP) | VAF 152/816 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58106102; called by muse, mutect2, varscan2
- KRT6C | c.567G>T p.K189N | Missense Mutation (SNP) | VAF 175/998 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52879208; called by muse, mutect2, varscan2
- LILRB4 | c.743C>A p.S248* | Nonsense Mutation (SNP) | VAF 33/284 reads (12%) | catalogued as COSV54405497; called by muse, mutect2, varscan2
- LIPK | c.573G>T p.K191N | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as rs1229915859, COSV68200705, COSV68200801; called by muse, mutect2, varscan2
- LRP1B | c.11248C>A p.H3750N | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV67273733; called by muse, mutect2, varscan2
- LRRC7 | c.3089C>A p.S1030Y (on ENST00000651989 / NM_001370785.2; = p.S997Y on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.423); catalogued as COSV99224574; called by muse, mutect2
- LRRC9 | c.161C>A p.P54H | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.141); catalogued as COSV54293370; called by muse, varscan2
- LRRK2 | c.1942G>T p.G648* | Nonsense Mutation (SNP) | VAF 49/217 reads (23%) | catalogued as rs76943330, COSV54170346; called by muse, mutect2, varscan2
- LSS | c.1313G>T p.R438L | Missense Mutation (SNP) | VAF 67/363 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as rs138907803; called by muse, mutect2, varscan2
- LYNX1-SLURP2 | c.347C>A p.P116H | Missense Mutation (SNP) | VAF 38/222 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58187032; called by muse, mutect2, varscan2
- MDGA2 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs762291569; called by muse, mutect2
- METTL23 | c.391A>T p.T131S | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV57973776; called by muse, mutect2, varscan2
- MFSD1 | c.752-1G>T p.X251_splice | Splice Site (SNP) | VAF 7/68 reads (10%) | catalogued as COSV51839760; called by mutect2, varscan2
- MYLK2 | c.140C>G p.P47R | Missense Mutation (SNP) | VAF 236/592 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); catalogued as COSV65659950; called by muse, varscan2
- MYO7A | c.6551C>A p.T2184K | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM165947, COSV60023826; called by muse, mutect2, varscan2
- NFXL1 | c.311A>T p.Q104L | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV61198033; called by muse, mutect2, varscan2
- NT5C1B | c.241C>A p.R81S | Missense Mutation (SNP) | VAF 114/569 reads (20%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); catalogued as rs113913452, COSV100409913; called by muse, mutect2, varscan2
- OR10H5 | c.799C>G p.Q267E | Missense Mutation (SNP) | VAF 51/275 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs1229311350, COSV58279091; called by muse, mutect2, varscan2
- OR2B6 | c.866T>C p.I289T | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776516996; called by muse, mutect2, varscan2
- OR2L5 | c.497C>A p.P166Q | Missense Mutation (SNP) | VAF 56/251 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV62365278; called by muse, mutect2, varscan2
- OR51T1 | c.34T>C p.S12P | Missense Mutation (SNP) | VAF 40/220 reads (18%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as rs763468779; called by muse, mutect2, varscan2
- OR6F1 | c.514C>A p.R172S | Missense Mutation (SNP) | VAF 138/581 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV100129402, COSV57469581; called by muse, mutect2, varscan2
- OTOL1 | c.836G>T p.R279L | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100019855, COSV60007961; called by muse, mutect2
- P2RY8 | c.256C>A p.R86S | Missense Mutation (SNP) | VAF 99/420 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV67178072; called by muse, mutect2, varscan2
- PAN2 | c.3131G>A p.G1044D (on ENST00000425394 / NM_001127460.3; = p.G1040D on NM_014871.5) | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56264163; called by mutect2, varscan2
- PARP1 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 154/682 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.115); catalogued as COSV64687311, COSV64687600, COSV64687699; called by muse, mutect2, varscan2
- PCDH11X | c.502G>T p.V168L | Missense Mutation (SNP) | VAF 134/261 reads (51%) | SIFT tolerated (0.33); PolyPhen benign (0.222); catalogued as COSV53438545, COSV53474797; called by muse, mutect2, varscan2
- PCDHA9 | c.28G>T p.E10* | Nonsense Mutation (SNP) | VAF 50/222 reads (23%) | catalogued as rs1314273290, COSV65327443, COSV65331749; called by muse, mutect2, varscan2
- PDS5B | c.1057+1G>A p.X353_splice | Splice Site (SNP) | VAF 9/127 reads (7%) | catalogued as COSV59729115; called by muse, mutect2
- PDZRN4 | c.2173A>G p.M725V (on ENST00000402685 / NM_001164595.2; = p.M467V on NM_013377.4) | Missense Mutation (SNP) | VAF 77/479 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs758188080; called by muse, mutect2, varscan2
- PGBD5 | c.1156G>T p.D386Y (on ENST00000525115; = p.D455Y on NM_001258311.2) | Missense Mutation (SNP) | VAF 76/310 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100358694; called by muse, mutect2, varscan2
- PLXNA4 | c.4444C>A p.R1482S | Missense Mutation (SNP) | VAF 51/482 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1203578232; called by muse, mutect2, varscan2
- PRSS1 | c.394C>A p.P132T | Missense Mutation (SNP) | VAF 120/518 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs1453661121, COSV104411420; called by muse, varscan2
- PRSS57 | c.608C>A p.T203N | Missense Mutation (SNP) | VAF 28/272 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs772328089; called by muse, mutect2
- PTCHD4 | c.2172C>G p.F724L | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); catalogued as COSV59776303, COSV59778896; called by muse, mutect2, varscan2
- PTPRB | c.4210G>T p.E1404* | Nonsense Mutation (SNP) | VAF 56/356 reads (16%) | catalogued as COSV54258944; called by muse, mutect2, varscan2
- PXDNL | c.2833G>A p.A945T | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV100685397, COSV62489203; called by muse, mutect2, varscan2
- REG1A | c.338G>T p.W113L | Missense Mutation (SNP) | VAF 33/242 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52071771; called by muse, mutect2, varscan2
- RFX6 | c.211G>T p.A71S | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs1273288733; called by muse, mutect2
- RUNDC3A | c.122C>A p.T41K | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99841681; called by muse, mutect2, varscan2
- RYR3 | c.9625C>G p.L3209V (on ENST00000389232; = p.L3210V on NM_001036.6) | Missense Mutation (SNP) | VAF 106/387 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1296762347, COSV66808597; called by muse, mutect2, varscan2
- SEMA3D | c.902C>T p.T301M | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs934585699; called by muse, mutect2
- SETD1A | c.1343G>A p.G448E | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.096); catalogued as rs1217253401; called by muse, mutect2, varscan2
- SFRP4 | c.238A>G p.M80V | Missense Mutation (SNP) | VAF 171/728 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs778897623, COSV52260934; called by muse, mutect2, varscan2
- SHROOM2 | c.3509G>T p.R1170L | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs769869968, COSV66608527; called by muse, mutect2, varscan2
- SI | c.2980G>T p.G994C | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs768991830, COSV100016383, COSV52303350; called by muse, mutect2, varscan2
- SULT1C3 | c.395G>A p.C132Y | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61253039; called by muse, mutect2, varscan2
- TATDN3 | c.5G>A p.R2Q | Missense Mutation (SNP) | VAF 138/499 reads (28%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.003); catalogued as rs767724016; called by muse, mutect2, varscan2
- TBC1D32 | c.2872G>T p.A958S | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51544082; called by muse, mutect2, varscan2
- TECTA | c.3106T>A p.C1036S | Missense Mutation (SNP) | VAF 109/519 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50790316; called by muse, mutect2, varscan2
- TENM1 | c.871C>A p.P291T | Missense Mutation (SNP) | VAF 74/134 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV64440836; called by muse, mutect2, varscan2
- TFAP2B | c.1222C>A p.P408T | Missense Mutation (SNP) | VAF 116/699 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53830965; called by muse, mutect2, varscan2
- TFAP2B | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 115/704 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777844146, COSV99540528; called by muse, mutect2, varscan2
- TLL1 | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 49/301 reads (16%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.019); catalogued as COSV50310222; called by muse, mutect2, varscan2
- TMPRSS6 | c.408G>T p.E136D | Missense Mutation (SNP) | VAF 133/579 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV60979794; called by muse, mutect2, varscan2
- TNR | c.2806G>T p.V936L | Missense Mutation (SNP) | VAF 70/289 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1004611621, COSV54918308; called by muse, mutect2, varscan2
- TNXB | c.11587C>G p.P3863A (on ENST00000647633; = p.P3616A on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 110/1158 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1439073426, COSV100926304; called by muse, mutect2
- TRIO | c.5668-1G>T p.X1890_splice | Splice Site (SNP) | VAF 139/438 reads (32%) | catalogued as COSV60098330; called by muse, mutect2, varscan2
- TRPM2 | c.799G>T p.D267Y | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1290766364; called by muse, mutect2, varscan2
- TTK | c.1984C>A p.L662I | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100036510; called by muse, mutect2, varscan2
- TTN | c.4055C>T p.P1352L (on ENST00000591111; = p.P1306L on NM_003319.4) | Missense Mutation (SNP) | VAF 46/254 reads (18%) | PolyPhen possibly damaging (0.523); catalogued as rs756380712, COSV60192126; called by muse, mutect2, varscan2
- TWF2 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 86/467 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.087); catalogued as rs199609796; called by muse, mutect2, varscan2
- UGT1A8 | c.760C>G p.R254G | Missense Mutation (SNP) | VAF 45/354 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65077439; called by muse, mutect2, varscan2
- UMOD | c.858C>A p.Y286* | Nonsense Mutation (SNP) | VAF 43/279 reads (15%) | catalogued as rs1334973619, COSV56778214; called by muse, mutect2, varscan2
- USH2A | c.10922G>A p.R3641K | Missense Mutation (SNP) | VAF 186/714 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.033); catalogued as rs397517969; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- WDR33 | c.2489C>T p.P830L | Missense Mutation (SNP) | VAF 58/281 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs773351587; called by muse, mutect2, varscan2
- WDR47 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 6/58 reads (10%) | catalogued as COSV63060312; called by muse, mutect2, varscan2
- WDR7 | c.4312G>T p.A1438S | Missense Mutation (SNP) | VAF 52/348 reads (15%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.978); catalogued as rs985453261; called by muse, mutect2, varscan2
- XIRP2 | c.6581C>T p.P2194L (on ENST00000628543; = p.P2369L on NM_152381.6) | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.046); catalogued as rs775614696; called by muse, mutect2, varscan2
- XYLT1 | c.1450C>T p.P484S | Missense Mutation (SNP) | VAF 116/488 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54482557; called by muse, mutect2, varscan2
- ABCA12 | c.7702G>C p.D2568H (on ENST00000272895 / NM_173076.3; = p.D2250H on NM_015657.3) | Missense Mutation (SNP) | VAF 62/305 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- ABCA2 | c.4226dup p.S1411Lfs*22 (on ENST00000614293; = p.S1381Lfs*22 on NM_001606.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 120/678 reads (18%) | called by mutect2, pindel, varscan2
- ACSM2B | c.213G>T p.W71C | Missense Mutation (SNP) | VAF 31/207 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- ADAMTS12 | c.4425G>T p.W1475C | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADCY2 | c.1013G>T p.G338V | Missense Mutation (SNP) | VAF 55/378 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADGRB1 | c.4364C>A p.P1455H | Missense Mutation (SNP) | VAF 61/377 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ADGRB3 | c.3200A>T p.E1067V | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- ADGRG4 | c.5315C>T p.T1772I | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ADGRL3 | c.3847C>A p.L1283M | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.963); called by muse, mutect2
- AGXT | c.1162C>G p.P388A | Missense Mutation (SNP) | VAF 147/772 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- AIRE | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 71/371 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- AKAP9 | c.387G>C p.K129N | Missense Mutation (SNP) | VAF 67/401 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- AL603832.3 | c.433G>T p.A145S | Missense Mutation (SNP) | VAF 35/386 reads (9%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2
- ANHX | c.862T>A p.L288M | Missense Mutation (SNP) | VAF 72/327 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- ANK2 | c.10883C>A p.A3628D | Missense Mutation (SNP) | VAF 45/237 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD17 | c.6284G>T p.S2095I | Missense Mutation (SNP) | VAF 146/876 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by mutect2, varscan2
- APIP | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2
- ARHGEF2 | c.1002G>C p.M334I (on ENST00000361247 / NM_001162383.2; = p.M306I on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 113/434 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- ARSI | c.1373T>A p.V458D | Missense Mutation (SNP) | VAF 41/217 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- ASB15 | c.1234C>G p.H412D | Missense Mutation (SNP) | VAF 40/239 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ATG13 | c.985del p.A329Qfs*57 (on ENST00000359513 / NM_001346321.1; = p.A292Qfs*57 on NM_014741.4 and 9 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 62/392 reads (16%) | called by mutect2, pindel, varscan2
- BMP1 | c.1961G>T p.G654V | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- BNC2 | c.1420G>T p.E474* | Nonsense Mutation (SNP) | VAF 119/699 reads (17%) | called by muse, mutect2, varscan2
- BORA | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BTBD8 | c.4585A>T p.S1529C (on ENST00000636805 / NM_001376131.1; = p.S1016C on NM_015237.4) | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- C11orf91 | c.247G>T p.G83C | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CACNA2D1 | c.1934C>G p.S645W (on ENST00000356253 / NM_001366867.1; = p.S633W on NM_000722.4) | Missense Mutation (SNP) | VAF 27/211 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- CALHM5 | c.676T>A p.L226M | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.804); called by muse, varscan2
- CAMK2B | c.518-1G>T p.X173_splice | Splice Site (SNP) | VAF 77/293 reads (26%) | called by muse, mutect2, varscan2
- CANT1 | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 60/337 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC175 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 39/240 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCDC60 | c.346T>C p.Y116H | Missense Mutation (SNP) | VAF 44/272 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CCDC78 | c.235C>T p.H79Y | Missense Mutation (SNP) | VAF 76/467 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- CD163 | c.174del p.N58Kfs*9 | Frame Shift Del (DEL) | VAF 27/169 reads (16%) | called by mutect2, pindel, varscan2
- CD163L1 | c.395G>T p.W132L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- CDH13 | c.1244C>A p.T415N | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CDKN2AIPNL | c.331A>G p.M111V | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CEACAM6 | c.361A>T p.T121S | Missense Mutation (SNP) | VAF 50/250 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- CENPW | c.47_48delinsC p.K16Tfs*7 | Frame Shift Del (DEL) | VAF 70/472 reads (15%) | called by pindel, varscan2*
- CFAP46 | c.4836G>T p.M1612I | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- CFAP92 | c.1126A>T p.S376C | Missense Mutation (SNP) | VAF 101/468 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- CFH | c.1012G>T p.E338* | Nonsense Mutation (SNP) | VAF 116/396 reads (29%) | called by muse, mutect2, varscan2
- CHST3 | c.394del p.R132Gfs*84 | Frame Shift Del (DEL) | VAF 70/467 reads (15%) | called by mutect2, pindel, varscan2
- CLIC4 | c.505G>T p.E169* | Nonsense Mutation (SNP) | VAF 40/228 reads (18%) | called by muse, mutect2, varscan2
- CPED1 | c.466C>G p.L156V | Missense Mutation (SNP) | VAF 48/291 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- CRB1 | c.1172-2A>C p.X391_splice | Splice Site (SNP) | VAF 75/312 reads (24%) | called by muse, mutect2, varscan2
- CYRIB | c.85A>T p.T29S | Missense Mutation (SNP) | VAF 50/314 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- DCAF12L1 | c.1139A>G p.Q380R | Missense Mutation (SNP) | VAF 123/228 reads (54%) | SIFT tolerated (0.16); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DGKB | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 26/169 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.599); called by muse, varscan2
- DGKQ | c.2581G>T p.V861F | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNAH7 | c.739G>C p.A247P | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DND1 | c.652C>A p.P218T | Missense Mutation (SNP) | VAF 100/508 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- DNMBP | c.2410G>T p.E804* | Nonsense Mutation (SNP) | VAF 31/143 reads (22%) | called by muse, mutect2, varscan2
- DPP8 | c.465A>T p.L155F (on ENST00000341861 / NM_001320875.2; = p.L139F on NM_017743.6) | Missense Mutation (SNP) | VAF 64/217 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DPY19L1 | c.347G>C p.W116S | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DSE | c.1186G>T p.D396Y | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- EFCAB8 | c.1744G>T p.G582C | Missense Mutation (SNP) | VAF 58/366 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EIF4G3 | c.4687G>T p.V1563L | Missense Mutation (SNP) | VAF 22/248 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.249); called by muse, mutect2
- ENGASE | c.366G>T p.R122S | Missense Mutation (SNP) | VAF 101/595 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- EPHB6 | c.3055T>A p.S1019T | Missense Mutation (SNP) | VAF 123/930 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- EXOSC7 | c.76G>T p.G26C | Missense Mutation (SNP) | VAF 56/290 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM135A | c.878del p.I293Kfs*11 (on ENST00000370479 / NM_001351599.1; = p.I276Kfs*11 on NM_020819.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 16/111 reads (14%) | called by mutect2, pindel, varscan2
- FAM171A1 | c.2187A>T p.R729S | Missense Mutation (SNP) | VAF 116/561 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM71E2 | c.316C>A p.L106M | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- FAM90A1 | c.1148C>A p.A383E | Missense Mutation (SNP) | VAF 218/1138 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- FASTKD5 | c.235G>T p.E79* | Nonsense Mutation (SNP) | VAF 29/207 reads (14%) | called by muse, mutect2, varscan2
- FBLN2 | c.1120C>A p.P374T | Missense Mutation (SNP) | VAF 48/282 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2
- FBXW5 | c.-17_12del | Translation Start Site (DEL) | VAF 17/166 reads (10%) | called by mutect2, pindel
- FERMT3 | c.958C>A p.L320M | Missense Mutation (SNP) | VAF 42/207 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- FH | c.555G>C p.Q185H | Missense Mutation (SNP) | VAF 60/225 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FKBP14 | c.399G>C p.E133D | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FLG | c.9583T>A p.S3195T | Missense Mutation (SNP) | VAF 320/1120 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- FLT1 | c.555C>G p.I185M | Missense Mutation (SNP) | VAF 59/274 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- FMN2 | c.3301C>A p.P1101T | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.66); called by muse, varscan2
- FOXC2 | c.1396C>T p.L466F | Missense Mutation (SNP) | VAF 80/864 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2
- GABBR1 | c.774G>T p.R258S | Missense Mutation (SNP) | VAF 48/196 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GASK1A | c.463del p.Q155Sfs*37 | Frame Shift Del (DEL) | VAF 28/224 reads (13%) | called by mutect2, pindel, varscan2
- GLI1 | c.2757del p.A920Pfs*26 | Frame Shift Del (DEL) | VAF 22/140 reads (16%) | called by pindel, varscan2
- GLI2 | c.2252T>A p.L751Q (on ENST00000361492 / NM_001374353.1; = p.L768Q on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- GLIS1 | c.1780G>T p.G594C | Missense Mutation (SNP) | VAF 30/441 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- GRAMD1B | c.203T>G p.L68W | Missense Mutation (SNP) | VAF 82/431 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- GREM2 | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 124/596 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRM8 | c.626T>A p.I209N | Missense Mutation (SNP) | VAF 49/328 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GTSF1 | c.22T>A p.S8T | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- GUCY2F | c.2495C>A p.S832Y | Missense Mutation (SNP) | VAF 64/125 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- HEATR1 | c.3840G>T p.E1280D | Missense Mutation (SNP) | VAF 62/276 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- HERC5 | c.404T>G p.L135* | Nonsense Mutation (SNP) | VAF 28/158 reads (18%) | called by muse, mutect2, varscan2
- HRC | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 86/468 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- HTT | c.2468G>T p.C823F | Missense Mutation (SNP) | VAF 66/381 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IFNA4 | c.90C>A p.H30Q | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- IGHA2 | c.172G>T p.D58Y | Missense Mutation (SNP) | VAF 119/569 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- IGHA2 | c.171G>T p.Q57H | Missense Mutation (SNP) | VAF 120/572 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- IGLV3-22 | c.205G>C p.D69H | Missense Mutation (SNP) | VAF 67/366 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- INPP5D | c.896T>C p.V299A (on ENST00000445964 / NM_001017915.3; = p.V298A on NM_005541.5) | Missense Mutation (SNP) | VAF 16/506 reads (3%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.916); called by muse, mutect2
- JAG1 | c.3128A>T p.D1043V | Missense Mutation (SNP) | VAF 104/731 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KCNH7 | c.2210A>T p.Q737L | Missense Mutation (SNP) | VAF 56/280 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KCNS2 | c.1374C>A p.S458R | Missense Mutation (SNP) | VAF 36/203 reads (18%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- KCNT1 | c.3659G>A p.C1220Y (on ENST00000488444; = p.C1225Y on NM_020822.3) | Missense Mutation (SNP) | VAF 64/326 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- KCNT2 | c.2865del p.I956Lfs*22 | Frame Shift Del (DEL) | VAF 66/326 reads (20%) | called by mutect2, pindel, varscan2
- KIAA1549L | c.3617G>A p.R1206K (on ENST00000321505; = p.R1503K on NM_012194.3) | Missense Mutation (SNP) | VAF 87/408 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KLHDC7A | c.1965G>T p.Q655H | Missense Mutation (SNP) | VAF 49/476 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KREMEN2 | c.89G>T p.S30I | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- KRT23 | c.202C>A p.L68I | Missense Mutation (SNP) | VAF 69/271 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KRT39 | c.145del p.H49Tfs*24 | Frame Shift Del (DEL) | VAF 52/307 reads (17%) | called by mutect2, pindel, varscan2
- KRT77 | c.759-8C>A | Splice Region (SNP) | VAF 78/337 reads (23%) | called by muse, mutect2, varscan2
- LAMA4 | c.2245C>T p.Q749* (on ENST00000230538 / NM_001105206.3; = p.Q742* on NM_002290.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 68/486 reads (14%) | called by muse, mutect2, varscan2
- LAMB3 | c.1012G>T p.A338S | Missense Mutation (SNP) | VAF 303/980 reads (31%) | SIFT tolerated (0.67); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- LAT2 | c.658C>A p.P220T | Missense Mutation (SNP) | VAF 63/288 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- LIN9 | c.1079A>T p.Q360L (on ENST00000366808 / NM_001270410.2; = p.Q305L on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 162/597 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- LPXN | c.1053G>C p.E351D | Missense Mutation (SNP) | VAF 102/622 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- LRP1B | c.8969A>T p.K2990M | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- LRRC38 | c.209G>C p.R70P | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- LRRC4B | c.226G>T p.D76Y | Missense Mutation (SNP) | VAF 58/453 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- LRRC7 | c.667C>A p.Q223K (on ENST00000651989 / NM_001370785.2; = p.Q190K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- LTBP1 | c.5del p.A2Gfs*44 | Frame Shift Del (DEL) | VAF 11/60 reads (18%) | called by mutect2, varscan2
- LTBP1 | c.10del p.A4Pfs*42 | Frame Shift Del (DEL) | VAF 10/73 reads (14%) | called by mutect2*, pindel, varscan2*
- MAP3K12 | c.2298A>T p.E766D | Missense Mutation (SNP) | VAF 111/582 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAX | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 174/831 reads (21%) | called by muse, mutect2, varscan2
- MCM8 | c.1411G>T p.A471S | Missense Mutation (SNP) | VAF 57/157 reads (36%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- MCPH1 | c.2206G>T p.A736S | Missense Mutation (SNP) | VAF 38/426 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); called by muse, mutect2
- MGAM2 | c.3816G>C p.L1272F | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MGAT5B | c.1729G>T p.E577* (on ENST00000569840 / NM_001199172.2; = p.E575* on NM_144677.3) | Nonsense Mutation (SNP) | VAF 14/69 reads (20%) | called by muse, mutect2, varscan2
- MIA2 | c.1323A>C p.E441D | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, varscan2
- MMP21 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- MPP3 | c.845G>T p.R282L | Missense Mutation (SNP) | VAF 67/414 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MRC1 | c.67A>T p.R23W | Missense Mutation (SNP) | VAF 63/429 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- MTUS2 | c.2923A>C p.T975P | Missense Mutation (SNP) | VAF 49/273 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MUC17 | c.7728A>T p.L2576F | Missense Mutation (SNP) | VAF 48/203 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- MYADML2 | c.878T>G p.V293G | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.081); called by muse, varscan2
- MYB | c.1875A>T p.Q625H | Missense Mutation (SNP) | VAF 35/220 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- MYL2 | c.282C>A p.D94E | Missense Mutation (SNP) | VAF 123/681 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- MYO3B | c.758C>A p.P253Q | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MYO7B | c.73G>C p.G25R | Missense Mutation (SNP) | VAF 38/250 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NCOA1 | c.1078G>T p.G360* | Nonsense Mutation (SNP) | VAF 45/192 reads (23%) | called by muse, mutect2, varscan2
- NCR3LG1 | c.16G>T p.A6S | Missense Mutation (SNP) | VAF 52/240 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- NFXL1 | c.1058G>T p.S353I | Missense Mutation (SNP) | VAF 46/226 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- NKX2-4 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 49/1001 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NLRP14 | c.57G>T p.L19F | Missense Mutation (SNP) | VAF 41/191 reads (21%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- NPHP4 | c.2176G>T p.G726C | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- NSMCE1 | c.398T>G p.V133G | Missense Mutation (SNP) | VAF 80/487 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- OBSCN | c.13690G>T p.G4564W | Missense Mutation (SNP) | VAF 148/447 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- OR14K1 | c.649G>C p.V217L | Missense Mutation (SNP) | VAF 141/642 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- OR2T10 | c.722G>T p.C241F | Missense Mutation (SNP) | VAF 70/258 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR4C12 | c.94C>A p.L32I | Missense Mutation (SNP) | VAF 44/196 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR51S1 | c.577G>T p.A193S | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR51T1 | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 41/223 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- OR5AN1 | c.453G>T p.M151I | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.89); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- OR5D18 | c.439G>T p.V147L | Missense Mutation (SNP) | VAF 39/236 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OTUD6A | c.829G>T p.A277S | Missense Mutation (SNP) | VAF 36/59 reads (61%) | SIFT tolerated (0.21); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- PADI3 | c.1395G>T p.W465C | Missense Mutation (SNP) | VAF 125/515 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB4 | c.2263A>T p.T755S | Missense Mutation (SNP) | VAF 108/707 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PCYT2 | c.760-2A>T p.X254_splice | Splice Site (SNP) | VAF 10/96 reads (10%) | called by muse, mutect2, varscan2
- PDE7B | c.1339G>T p.G447C | Missense Mutation (SNP) | VAF 67/411 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- PDGFRA | c.1327C>A p.P443T | Missense Mutation (SNP) | VAF 49/290 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PDZD2 | c.359G>T p.W120L | Missense Mutation (SNP) | VAF 157/987 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PEG3 | c.4099G>T p.A1367S | Missense Mutation (SNP) | VAF 52/227 reads (23%) | SIFT tolerated (0.68); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PGLYRP2 | c.838G>T p.V280F | Missense Mutation (SNP) | VAF 69/390 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PKD1L3 | c.3404T>C p.I1135T | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.212); called by mutect2, varscan2
- PLXNA4 | c.5315C>A p.S1772Y | Missense Mutation (SNP) | VAF 112/591 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLXND1 | c.1240G>T p.D414Y | Missense Mutation (SNP) | VAF 67/304 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- PNPLA7 | c.977A>T p.K326M | Missense Mutation (SNP) | VAF 56/245 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- POM121 | c.3001G>T p.A1001S (on ENST00000434423; = p.A736S on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- PRAMEF20 | c.497G>T p.C166F | Missense Mutation (SNP) | VAF 152/745 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PRB2 | c.1213C>A p.P405T | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- PRSS57 | c.606C>A p.C202* | Nonsense Mutation (SNP) | VAF 28/276 reads (10%) | called by muse, mutect2
- PSG6 | c.783T>A p.C261* | Nonsense Mutation (SNP) | VAF 46/448 reads (10%) | called by muse, mutect2, varscan2
- PTGER3 | c.1127C>A p.S376Y | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- PTPRR | c.1798G>C p.A600P | Missense Mutation (SNP) | VAF 48/259 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBFOX3 | c.551G>T p.G184V | Missense Mutation (SNP) | VAF 113/577 reads (20%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- RCBTB2 | c.1002G>T p.W334C | Missense Mutation (SNP) | VAF 45/397 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RCC1L | c.1006G>T p.G336W | Missense Mutation (SNP) | VAF 137/750 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RELN | c.385del p.V129* | Frame Shift Del (DEL) | VAF 41/354 reads (12%) | called by mutect2, pindel, varscan2
- REXO1 | c.1610G>T p.S537I | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- RGPD4 | c.3689G>T p.G1230V | Missense Mutation (SNP) | VAF 63/445 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- RGS21 | c.433C>T p.H145Y | Missense Mutation (SNP) | VAF 66/238 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- RNF145 | c.1749G>T p.Q583H (on ENST00000424310 / NM_001199383.2; = p.Q611H on NM_144726.2) | Missense Mutation (SNP) | VAF 37/212 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- RYR2 | c.13141G>A p.G4381S | Missense Mutation (SNP) | VAF 124/354 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RYR3 | c.6854T>A p.M2285K (on ENST00000389232; = p.M2286K on NM_001036.6) | Missense Mutation (SNP) | VAF 59/224 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- SALL3 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SARDH | c.1471-2A>T p.X491_splice | Splice Site (SNP) | VAF 69/309 reads (22%) | called by muse, mutect2, varscan2
- SARDH | c.823del p.A275Qfs*119 | Frame Shift Del (DEL) | VAF 46/232 reads (20%) | called by mutect2, pindel, varscan2
- SDK2 | c.3143C>A p.S1048Y | Missense Mutation (SNP) | VAF 44/254 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- SEM1 | c.114G>T p.Q38H | Missense Mutation (SNP) | VAF 141/821 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- SGSM2 | c.2062_2074del p.G688Wfs*32 (on ENST00000426855 / NM_001098509.2; = p.G733Wfs*32 on NM_014853.3) | Frame Shift Del (DEL) | VAF 93/360 reads (26%) | called by mutect2, pindel, varscan2
- SH3TC2 | c.2291C>A p.S764Y | Missense Mutation (SNP) | VAF 72/387 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- SHANK2 | c.3931G>T p.A1311S | Missense Mutation (SNP) | VAF 147/762 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SHISAL2B | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 22/102 reads (22%) | called by muse, mutect2, varscan2
- SIGLEC16 | c.274G>T p.G92W | Missense Mutation (SNP) | VAF 34/582 reads (6%) | called by muse, mutect2
- SLC11A2 | c.1673G>T p.C558F (on ENST00000394904 / NM_001379455.1; = p.C529F on NM_000617.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/229 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- SLC22A14 | c.1413dup p.P472Sfs*33 | Frame Shift Ins (INS) | VAF 42/195 reads (22%) | called by pindel, varscan2
- SLC6A18 | c.846-1G>T p.X282_splice | Splice Site (SNP) | VAF 47/281 reads (17%) | called by muse, mutect2, varscan2
- SLC6A7 | c.1120G>T p.A374S | Missense Mutation (SNP) | VAF 58/332 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLK | c.2592G>T p.E864D | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SNTG1 | c.466+1G>T p.X156_splice | Splice Site (SNP) | VAF 17/104 reads (16%) | called by muse, mutect2, varscan2
- SNTG1 | c.1280C>T p.T427I | Missense Mutation (SNP) | VAF 28/169 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- SOWAHD | c.107C>A p.T36N | Missense Mutation (SNP) | VAF 108/201 reads (54%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- SOX18 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 122/914 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SOX6 | c.1136T>C p.V379A (on ENST00000528429 / NM_001145819.2; = p.V338A on NM_017508.3) | Missense Mutation (SNP) | VAF 94/357 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- SP140 | c.87G>T p.E29D | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.827); called by muse, mutect2
- SPTA1 | c.2786C>A p.A929D | Missense Mutation (SNP) | VAF 102/459 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ST6GAL2 | c.1102G>T p.V368L | Missense Mutation (SNP) | VAF 28/140 reads (20%) | PolyPhen benign (0.204); called by muse, mutect2, varscan2
- ST6GAL2 | c.217G>T p.G73C | Missense Mutation (SNP) | VAF 26/133 reads (20%) | PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- STK39 | c.1638A>T p.*546Cext*53 | Nonstop Mutation (SNP) | VAF 45/221 reads (20%) | called by muse, varscan2
- TG | c.5924G>T p.G1975V | Missense Mutation (SNP) | VAF 43/285 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- TLR4 | c.1000C>A p.H334N (on ENST00000355622 / NM_138554.5; = p.H294N on NM_003266.4) | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- TMC5 | c.1364G>T p.W455L (on ENST00000396229 / NM_001105248.1; = p.W209L on NM_024780.5) | Missense Mutation (SNP) | VAF 120/563 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM236 | c.743C>A p.T248K | Missense Mutation (SNP) | VAF 198/1090 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TNC | c.1615_1617delinsTT p.Q539Lfs*5 | Frame Shift Del (DEL) | VAF 70/397 reads (18%) | called by pindel, varscan2*
- TNNI1 | c.23C>A p.P8H | Missense Mutation (SNP) | VAF 134/464 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- TPTE2 | c.924G>T p.M308I (on ENST00000400230 / NM_199254.2; = p.M231I on NM_130785.3) | Missense Mutation (SNP) | VAF 15/183 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- TRPC4 | c.941G>T p.W314L | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- TSPAN14 | c.201G>T p.M67I | Missense Mutation (SNP) | VAF 103/581 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC9C | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 144/890 reads (16%) | called by muse, mutect2, varscan2
- TTK | c.1983G>C p.K661N | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.14082C>G p.I4694M (on ENST00000591111; = p.I3767M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/106 reads (23%) | PolyPhen benign (0.033); called by muse, mutect2, varscan2
- TUBB7P | n.57+1G>T | Splice Site (SNP) | VAF 32/453 reads (7%) | called by muse, mutect2
- UGT2B7 | c.1123G>T p.G375C | Missense Mutation (SNP) | VAF 42/201 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- UNC79 | c.3469G>C p.D1157H (on ENST00000393151 / NM_001346218.2; = p.D980H on NM_020818.5) | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- UQCC1 | c.333G>T p.W111C | Missense Mutation (SNP) | VAF 36/230 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- USP33 | c.1234A>G p.I412V | Missense Mutation (SNP) | VAF 46/192 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VAT1L | c.500C>G p.T167R | Missense Mutation (SNP) | VAF 57/679 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.216); called by muse, mutect2
- VCAN | c.2687C>A p.T896N | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- VCX3A | c.261C>A p.H87Q | Missense Mutation (SNP) | VAF 55/680 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.005); called by muse, varscan2
- VLDLR | c.2105-2A>T p.X702_splice | Splice Site (SNP) | VAF 57/301 reads (19%) | called by muse, mutect2, varscan2
- VMAC | c.301G>T p.A101S | Missense Mutation (SNP) | VAF 48/444 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- VPS35 | c.1950G>T p.R650S | Missense Mutation (SNP) | VAF 44/482 reads (9%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.988); called by muse, mutect2
- VTCN1 | c.389G>A p.C130Y | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- WASHC2A | c.2651A>T p.D884V | Missense Mutation (SNP) | VAF 38/369 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- WDR97 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 44/265 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- XDH | c.1523G>T p.R508L | Missense Mutation (SNP) | VAF 134/742 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- ZC3H18 | c.2270-1G>T p.X757_splice | Splice Site (SNP) | VAF 32/245 reads (13%) | called by muse, mutect2
- ZFAND1 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 76/362 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZFP42 | c.435G>C p.E145D | Missense Mutation (SNP) | VAF 70/329 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- ZNF257 | c.346G>T p.G116C | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF337 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 134/439 reads (31%) | called by muse, mutect2, varscan2
- ZNF354A | c.1492G>T p.E498* | Nonsense Mutation (SNP) | VAF 39/260 reads (15%) | called by muse, mutect2, varscan2
- ZNF568 | c.854G>T p.C285F | Missense Mutation (SNP) | VAF 21/241 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.033); called by muse, mutect2
- ZNF705D | c.790G>T p.A264S | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- ZNF714 | c.955G>T p.G319C | Missense Mutation (SNP) | VAF 17/173 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF729 | c.2182A>G p.T728A | Missense Mutation (SNP) | VAF 37/212 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- ZP1 | c.1112+1G>A p.X371_splice | Splice Site (SNP) | VAF 58/275 reads (21%) | called by muse, mutect2, varscan2
- ABCB8 | c.1842G>A p.G614= (on ENST00000297504 / NM_001282291.2; = p.G597= on NM_007188.5) | Silent (SNP) | VAF 40/185 reads (22%) | called by muse, mutect2, varscan2
- ABCC2 | c.1104C>T p.F368= | Silent (SNP) | VAF 127/693 reads (18%) | called by muse, mutect2, varscan2
- ACVR1C | c.9G>T p.R3= | Silent (SNP) | VAF 61/294 reads (21%) | called by muse, mutect2, varscan2
- ADAMTS18 | c.96C>A p.L32= | Silent (SNP) | VAF 77/354 reads (22%) | called by muse, mutect2, varscan2
- AHNAK2 | c.13701C>T p.D4567= | Silent (SNP) | VAF 100/446 reads (22%) | catalogued as rs749006512, COSV60909490; called by muse, mutect2, varscan2
- ALDH1A2 | c.699C>A p.P233= | Silent (SNP) | VAF 76/280 reads (27%) | catalogued as COSV51097285; called by muse, mutect2, varscan2
- ANGPT1 | c.330G>T p.S110= | Silent (SNP) | VAF 33/132 reads (25%) | called by muse, mutect2, varscan2
- ANKRD17 | c.6285C>T p.S2095= | Silent (SNP) | VAF 150/897 reads (17%) | catalogued as rs772402734; called by muse, mutect2, varscan2
- APOB | c.8760A>G p.A2920= | Silent (SNP) | VAF 9/84 reads (11%) | called by muse, mutect2
- BDP1 | c.5472G>A p.E1824= | Silent (SNP) | VAF 37/225 reads (16%) | called by muse, mutect2, varscan2
- BICC1 | c.246G>A p.E82= | Silent (SNP) | VAF 36/202 reads (18%) | catalogued as rs371307045; called by muse, mutect2, varscan2
- CALCR | c.1269C>A p.A423= (on ENST00000649521 / NM_001164737.2; = p.A407= on NM_001742.4) | Silent (SNP) | VAF 26/180 reads (14%) | called by muse, mutect2, varscan2
- CALHM5 | c.675G>A p.Q225= | Silent (SNP) | VAF 18/150 reads (12%) | called by muse, varscan2
- CCSER1 | c.2034G>T p.S678= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as rs373571745, COSV100389979, COSV100397877; called by muse, mutect2, varscan2
- CDK14 | c.582G>T p.V194= (on ENST00000380050 / NM_001287135.2; = p.V176= on NM_012395.3) | Silent (SNP) | VAF 16/145 reads (11%) | called by muse, mutect2, varscan2
- CELF4 | c.120G>T p.P40= | Silent (SNP) | VAF 69/395 reads (17%) | called by muse, mutect2, varscan2
- CEP295 | c.3159A>T p.L1053= | Silent (SNP) | VAF 23/140 reads (16%) | called by muse, mutect2, varscan2
- CEP350 | c.7935G>A p.G2645= | Silent (SNP) | VAF 33/171 reads (19%) | called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.912A>T p.S304= | Silent (SNP) | VAF 71/436 reads (16%) | called by muse, mutect2, varscan2
- CFAP46 | c.3315C>T p.D1105= | Silent (SNP) | VAF 17/270 reads (6%) | catalogued as rs969722723, COSV63951637; called by muse, mutect2
- CNTN5 | c.735G>T p.R245= | Silent (SNP) | VAF 57/314 reads (18%) | called by muse, mutect2, varscan2
- CYP26C1 | c.522G>C p.A174= | Silent (SNP) | VAF 69/363 reads (19%) | catalogued as rs1408332340; called by muse, mutect2, varscan2
- CYP4F11 | c.1128C>A p.A376= | Silent (SNP) | VAF 30/372 reads (8%) | called by muse, mutect2
- DACH1 | c.2178G>T p.L726= (on ENST00000619232 / NM_001366712.1; = p.L472= on NM_004392.6) | Silent (SNP) | VAF 42/302 reads (14%) | called by muse, mutect2, varscan2
- DES | c.1080C>A p.A360= | Silent (SNP) | VAF 71/393 reads (18%) | catalogued as COSV64660077; called by muse, mutect2, varscan2
- DMBT1 | c.5104C>T p.L1702= (on ENST00000338354 / NM_001377530.1; = p.L945= on NM_004406.3) | Silent (SNP) | VAF 156/1043 reads (15%) | called by muse, mutect2, varscan2
- DNASE1L3 | c.891G>A p.R297= | Silent (SNP) | VAF 64/337 reads (19%) | called by muse, mutect2, varscan2
- DOK7 | c.730C>A p.R244= | Silent (SNP) | VAF 79/430 reads (18%) | called by muse, mutect2, varscan2
- FOXF2 | c.111C>A p.A37= | Silent (SNP) | VAF 29/167 reads (17%) | called by muse, mutect2, varscan2
- FYN | c.1104G>C p.V368= | Silent (SNP) | VAF 19/150 reads (13%) | catalogued as COSV99992141; called by muse, mutect2, varscan2
- GAK | c.3102G>T p.L1034= | Silent (SNP) | VAF 100/524 reads (19%) | called by muse, mutect2, varscan2
- GALNT12 | c.624G>T p.L208= | Silent (SNP) | VAF 88/454 reads (19%) | called by muse, mutect2, varscan2
- GC | c.138C>A p.V46= | Silent (SNP) | VAF 41/205 reads (20%) | catalogued as COSV56735678, COSV99909497; called by muse, mutect2, varscan2
- GLYATL3 | c.348G>T p.A116= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as COSV64592569; called by muse, mutect2, varscan2
- GMNN | c.327G>T p.A109= | Silent (SNP) | VAF 36/201 reads (18%) | called by muse, varscan2
- GOT2 | c.1287C>T p.T429= | Silent (SNP) | VAF 27/235 reads (11%) | called by muse, mutect2, varscan2
- GPR42 | c.190C>T p.L64= | Silent (SNP) | VAF 54/808 reads (7%) | called by muse, mutect2
- HCN1 | c.2538G>T p.S846= | Silent (SNP) | VAF 43/315 reads (14%) | called by muse, mutect2, varscan2
- HEATR9 | c.279G>A p.R93= | Silent (SNP) | VAF 80/348 reads (23%) | catalogued as rs758350445; called by muse, varscan2
- HECTD4 | c.6984G>T p.V2328= | Silent (SNP) | VAF 41/196 reads (21%) | called by muse, mutect2, varscan2
- HK1 | c.1566G>T p.G522= | Silent (SNP) | VAF 45/266 reads (17%) | called by muse, mutect2, varscan2
- HMGCLL1 | c.918C>A p.S306= | Silent (SNP) | VAF 11/89 reads (12%) | called by muse, mutect2, varscan2
- HNRNPH1 | c.807A>T p.S269= | Silent (SNP) | VAF 59/296 reads (20%) | called by muse, mutect2, varscan2
- INSL4 | c.390C>T p.D130= | Silent (SNP) | VAF 28/143 reads (20%) | catalogued as rs200209059, COSV53328956; called by muse, mutect2, varscan2
- IVNS1ABP | c.1347G>A p.L449= | Silent (SNP) | VAF 29/161 reads (18%) | called by muse, mutect2, varscan2
- KRT34 | c.465C>A p.L155= | Silent (SNP) | VAF 46/235 reads (20%) | catalogued as COSV101222584; called by muse, mutect2, varscan2
- KRTAP4-8 | c.531C>A p.P177= | Silent (SNP) | VAF 18/121 reads (15%) | catalogued as rs765969753, COSV61563936; called by muse, mutect2, varscan2
- LAMB3 | c.1011G>T p.G337= | Silent (SNP) | VAF 296/968 reads (31%) | called by muse, mutect2, varscan2
- LOXL2 | c.597C>A p.T199= | Silent (SNP) | VAF 78/866 reads (9%) | called by muse, mutect2
- LRP2 | c.8589G>A p.T2863= | Silent (SNP) | VAF 73/414 reads (18%) | catalogued as rs762415291, COSV55542262; called by muse, mutect2
- LRRC29 | c.223C>A p.R75= | Silent (SNP) | VAF 25/178 reads (14%) | catalogued as rs751766015, COSV58527146; called by muse, mutect2, varscan2
- LYPD6 | c.297G>T p.L99= | Silent (SNP) | VAF 18/169 reads (11%) | called by muse, mutect2, varscan2
- M1AP | c.957C>T p.C319= | Silent (SNP) | VAF 20/187 reads (11%) | catalogued as rs575443272; called by muse, mutect2, varscan2
- MICALL2 | c.1644G>T p.V548= | Silent (SNP) | VAF 126/506 reads (25%) | called by muse, mutect2, varscan2
- MPL | c.6C>A p.P2= | Silent (SNP) | VAF 143/674 reads (21%) | called by muse, mutect2, varscan2
- MRPL44 | c.507G>T p.V169= | Silent (SNP) | VAF 49/266 reads (18%) | called by muse, mutect2, varscan2
- MTHFD1L | c.1857G>T p.T619= | Silent (SNP) | VAF 67/355 reads (19%) | called by muse, mutect2, varscan2
- MUC16 | c.37785C>A p.G12595= | Silent (SNP) | VAF 45/391 reads (12%) | called by muse, mutect2, varscan2
- MYL1 | c.102A>G p.K34= | Silent (SNP) | VAF 30/652 reads (5%) | called by muse, mutect2
- NALCN | c.171G>T p.T57= | Silent (SNP) | VAF 12/123 reads (10%) | catalogued as COSV99218448; called by muse, mutect2
- NCOA6 | c.4227G>A p.G1409= | Silent (SNP) | VAF 84/443 reads (19%) | catalogued as rs766683233; called by muse, mutect2, varscan2
- NHLH1 | c.189C>T p.R63= | Silent (SNP) | VAF 44/652 reads (7%) | catalogued as COSV100131476; called by muse, mutect2
- NRXN3 | c.2445G>T p.T815= (on ENST00000335750 / NM_001330195.2; = p.T442= on NM_004796.6) | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as rs371473443; called by muse, mutect2
- OLFML1 | c.289C>A p.R97= | Silent (SNP) | VAF 49/330 reads (15%) | catalogued as rs143669812; called by muse, mutect2, varscan2
- OR10G7 | c.717C>T p.T239= | Silent (SNP) | VAF 58/341 reads (17%) | called by muse, mutect2, varscan2
- PAPPA | c.1185G>T p.L395= | Silent (SNP) | VAF 110/608 reads (18%) | catalogued as COSV60277504; called by muse, mutect2, varscan2
- PCDHA1 | c.1410G>T p.P470= | Silent (SNP) | VAF 203/977 reads (21%) | called by muse, mutect2, varscan2
- PCDHB4 | c.1590G>T p.V530= | Silent (SNP) | VAF 215/1208 reads (18%) | catalogued as rs1431857626, COSV52023398; called by muse, varscan2
- PKD1L3 | c.1044C>A p.G348= | Silent (SNP) | VAF 27/151 reads (18%) | called by muse, mutect2, varscan2
- PKHD1 | c.1305G>T p.G435= | Silent (SNP) | VAF 65/350 reads (19%) | called by muse, mutect2, varscan2
- PKNOX2 | c.465C>T p.C155= | Silent (SNP) | VAF 41/227 reads (18%) | called by muse, mutect2, varscan2
- PLG | c.1572G>C p.A524= | Silent (SNP) | VAF 72/504 reads (14%) | catalogued as COSV51980433; called by muse, mutect2, varscan2
- PLXNA4 | c.3621C>T p.I1207= | Silent (SNP) | VAF 43/285 reads (15%) | catalogued as rs748028600, COSV58159508; called by muse, mutect2, varscan2
- PROX1 | c.1596C>T p.H532= | Silent (SNP) | VAF 32/200 reads (16%) | called by muse, mutect2, varscan2
- PTPRB | c.4209G>T p.L1403= | Silent (SNP) | VAF 54/355 reads (15%) | catalogued as COSV54245049; called by muse, mutect2, varscan2
- RYR1 | c.366C>A p.T122= | Silent (SNP) | VAF 58/704 reads (8%) | called by muse, mutect2
- SALL1 | c.3945G>A p.V1315= | Silent (SNP) | VAF 31/424 reads (7%) | called by muse, mutect2
- SETBP1 | c.4761C>A p.S1587= | Silent (SNP) | VAF 66/353 reads (19%) | called by muse, mutect2, varscan2
- SLC45A3 | c.1410A>T p.V470= | Silent (SNP) | VAF 75/253 reads (30%) | called by muse, mutect2, varscan2
- SLC5A5 | c.1134G>A p.L378= | Silent (SNP) | VAF 111/459 reads (24%) | called by muse, mutect2, varscan2
- SLC5A8 | c.315G>T p.P105= | Silent (SNP) | VAF 28/155 reads (18%) | called by muse, mutect2, varscan2
- SMYD4 | c.534C>T p.A178= | Silent (SNP) | VAF 102/454 reads (22%) | catalogued as rs1348586625, COSV100563027; called by muse, mutect2, varscan2
- SPAST | c.108C>T p.A36= | Silent (SNP) | VAF 68/383 reads (18%) | catalogued as rs1261214882; called by muse, mutect2, varscan2
- SPRR1B | c.201C>T p.P67= | Silent (SNP) | VAF 101/521 reads (19%) | catalogued as rs1042760647, COSV61067557; called by muse, mutect2, varscan2
- SPTB | c.2493A>G p.Q831= | Silent (SNP) | VAF 54/209 reads (26%) | called by muse, mutect2, varscan2
- TNC | c.1467C>T p.D489= | Silent (SNP) | VAF 85/401 reads (21%) | catalogued as rs559495675, COSV60785697; called by muse, mutect2, varscan2
- TNRC18 | c.4234C>T p.L1412= | Silent (SNP) | VAF 43/125 reads (34%) | catalogued as rs771115682; called by muse, mutect2, varscan2
- TRIM58 | c.387G>T p.T129= | Silent (SNP) | VAF 26/88 reads (30%) | called by muse, mutect2, varscan2
- TTC5 | c.414C>G p.S138= | Silent (SNP) | VAF 112/884 reads (13%) | called by muse, mutect2, varscan2
- TXLNB | c.75C>A p.P25= | Silent (SNP) | VAF 51/258 reads (20%) | catalogued as COSV64444811; called by muse, mutect2, varscan2
- WDR7 | c.4311G>T p.S1437= | Silent (SNP) | VAF 54/346 reads (16%) | catalogued as COSV99589702; called by muse, mutect2, varscan2
- ZBBX | c.2232T>A p.L744= | Silent (SNP) | VAF 28/128 reads (22%) | called by muse, mutect2, varscan2
- ZIC1 | c.1035C>T p.N345= | Silent (SNP) | VAF 122/429 reads (28%) | called by muse, mutect2, varscan2
- ZNF33B | c.798G>A p.Q266= | Silent (SNP) | VAF 20/106 reads (19%) | called by muse, mutect2, varscan2
- AC006305.1 | n.1049C>A | RNA (SNP) | VAF 53/290 reads (18%) | catalogued as rs1246365628; called by muse, mutect2, varscan2
- AC009053.1 | n.1311C>T | RNA (SNP) | VAF 98/539 reads (18%) | catalogued as rs751651695; called by muse, mutect2, varscan2
- AC034105.1 | n.119A>T | RNA (SNP) | VAF 28/536 reads (5%) | called by muse, mutect2
- AC093791.1 | n.454A>G | RNA (SNP) | VAF 23/124 reads (19%) | called by muse, mutect2, varscan2
- AC133561.1 | n.1938C>A | RNA (SNP) | VAF 124/491 reads (25%) | called by muse, mutect2, varscan2
- ACTN1 | c.105+761G>T | Intron (SNP) | VAF 88/289 reads (30%) | called by muse, mutect2, varscan2
- ADARB2 | c.1865-1483G>T | Intron (SNP) | VAF 99/520 reads (19%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130915795 G>T | 5'Flank (SNP) | VAF 15/53 reads (28%) | called by muse, mutect2, varscan2
- ASH1L | c.5828+4891G>T | Intron (SNP) | VAF 152/556 reads (27%) | called by muse, mutect2, varscan2
- ASH1L | c.5828+4890G>T | Intron (SNP) | VAF 149/556 reads (27%) | called by muse, mutect2, varscan2
- BIRC8 | n.1336C>A | RNA (SNP) | VAF 38/414 reads (9%) | catalogued as COSV101461324; called by muse, mutect2
- CAB39L | c.-75T>C | 5'UTR (SNP) | VAF 14/143 reads (10%) | called by muse, mutect2, varscan2
- CAPNS1 | c.-15-21G>C | Intron (SNP) | VAF 36/342 reads (11%) | called by muse, varscan2
- CCDC74A | c.295+394G>T | Intron (SNP) | VAF 93/460 reads (20%) | called by muse, mutect2, varscan2
- CHD5 | c.*3391C>A | 3'UTR (SNP) | VAF 15/84 reads (18%) | called by muse, mutect2, varscan2
- COLEC11 | c.130+1713C>A | Intron (SNP) | VAF 78/452 reads (17%) | catalogued as rs1307581648; called by muse, mutect2, varscan2
- DLX6 | c.437-60G>T | Intron (SNP) | VAF 60/386 reads (16%) | called by muse, mutect2, varscan2
- DNM1L | c.-57C>T | 5'UTR (SNP) | VAF 51/309 reads (17%) | catalogued as rs748628452; called by muse, mutect2, varscan2
- ENGASE | c.*605A>T | 3'UTR (SNP) | VAF 69/365 reads (19%) | called by muse, mutect2, varscan2
- FAM182A | n.837T>C | RNA (SNP) | VAF 25/269 reads (9%) | catalogued as rs750808306; called by mutect2, varscan2
- FLRT2 | chr14:85529114 C>T | 5'Flank (SNP) | VAF 45/174 reads (26%) | called by muse, mutect2, varscan2
- GUSBP1 | n.180-10245G>T | Intron (SNP) | VAF 56/2014 reads (3%) | called by muse, mutect2
- GVINP1 | n.6207G>T | RNA (SNP) | VAF 9/41 reads (22%) | called by muse, mutect2, varscan2
- IL17B | c.-13G>T | 5'UTR (SNP) | VAF 52/301 reads (17%) | catalogued as COSV99938472; called by muse, mutect2, varscan2
- IMPDH1 | c.*18G>T | 3'UTR (SNP) | VAF 67/331 reads (20%) | called by muse, mutect2, varscan2
- ITGAL | c.62-180C>A | Intron (SNP) | VAF 69/370 reads (19%) | called by muse, mutect2, varscan2
- ITIH5 | c.653-2341C>G | Intron (SNP) | VAF 8/114 reads (7%) | called by muse, mutect2
- KHDC4 | c.-27G>T | 5'UTR (SNP) | VAF 112/289 reads (39%) | catalogued as rs777878781; called by muse, mutect2, varscan2
- KIR3DL2 | c.-32G>A | 5'UTR (SNP) | VAF 98/563 reads (17%) | called by muse, mutect2, varscan2
- LAMA1 | c.6775-49G>T | Intron (SNP) | VAF 54/246 reads (22%) | called by muse, mutect2, varscan2
- LEFTY2 | c.251-40G>T | Intron (SNP) | VAF 140/627 reads (22%) | called by muse, mutect2, varscan2
- LINC01235 | n.436G>T | RNA (SNP) | VAF 100/641 reads (16%) | called by muse, mutect2, varscan2
- LINC02610 | n.3075G>T | RNA (SNP) | VAF 40/139 reads (29%) | called by muse, mutect2, varscan2
- MGAT4FP | n.556T>A | RNA (SNP) | VAF 98/482 reads (20%) | called by muse, mutect2, varscan2
- MIR193A | n.86C>G | RNA (SNP) | VAF 24/149 reads (16%) | called by muse, mutect2, varscan2
- MIR519A1 | n.58G>T | RNA (SNP) | VAF 41/305 reads (13%) | called by muse, mutect2, varscan2
- MIR519A2 | n.72G>T | RNA (SNP) | VAF 34/301 reads (11%) | called by muse, mutect2, varscan2
- MIR521-2 | n.56C>A | RNA (SNP) | VAF 21/290 reads (7%) | called by muse, mutect2
- MIR557 | n.37G>T | RNA (SNP) | VAF 60/280 reads (21%) | called by muse, mutect2, varscan2
- MTRNR2L6 | chr7:142671130 G>A | 3'Flank (SNP) | VAF 35/166 reads (21%) | called by muse, mutect2, varscan2
- NFASC | c.91+2334C>T | Intron (SNP) | VAF 77/406 reads (19%) | called by muse, mutect2, varscan2
- NHS | c.566-52162G>T | Intron (SNP) | VAF 39/127 reads (31%) | called by muse, mutect2, varscan2
- NUB1 | c.416+617C>A | Intron (SNP) | VAF 67/332 reads (20%) | called by muse, mutect2, varscan2
- NUDT22 | c.481-84del | Intron (DEL) | VAF 43/263 reads (16%) | called by mutect2, pindel, varscan2
- NXF5 | n.1102C>A | RNA (SNP) | VAF 181/509 reads (36%) | called by muse, mutect2, varscan2
- OFCC1 | n.1530G>T | RNA (SNP) | VAF 40/177 reads (23%) | called by muse, mutect2, varscan2
- PANK4 | c.207+31G>T | Intron (SNP) | VAF 35/308 reads (11%) | called by muse, mutect2, varscan2
- PLCD3 | c.1712-34A>T | Intron (SNP) | VAF 45/211 reads (21%) | called by muse, mutect2, varscan2
- PLP1 | c.453+37G>T | Intron (SNP) | VAF 62/119 reads (52%) | called by muse, mutect2, varscan2
- PSG5 | c.431-2782C>A | Intron (SNP) | VAF 39/372 reads (10%) | catalogued as rs749690288, COSV61654297; called by muse, mutect2, varscan2
- RAN | c.248-505G>T | Intron (SNP) | VAF 24/124 reads (19%) | called by muse, mutect2, varscan2
- RASA4CP | n.202+2027_202+2028insT | Intron (INS) | VAF 102/486 reads (21%) | called by mutect2, pindel*, varscan2
- RAX | c.290-19C>T | Intron (SNP) | VAF 19/92 reads (21%) | catalogued as rs1160044105; called by muse, mutect2, varscan2
- RCC1L | c.584-31G>T | Intron (SNP) | VAF 69/585 reads (12%) | called by muse, mutect2, varscan2
- SEC13 | c.4-1124C>T | Intron (SNP) | VAF 57/281 reads (20%) | catalogued as rs1222885945; called by muse, mutect2, varscan2
- SPATA31C2 | n.821C>A | RNA (SNP) | VAF 123/812 reads (15%) | called by muse, mutect2, varscan2
- SYCE1 | chr10:133567960 G>T | 5'Flank (SNP) | VAF 12/107 reads (11%) | called by muse, mutect2, varscan2
- SYCE1 | chr10:133567961 G>T | 5'Flank (SNP) | VAF 13/109 reads (12%) | catalogued as rs767246023; called by muse, mutect2, varscan2
- TBC1D3P2 | n.777C>A | RNA (SNP) | VAF 94/610 reads (15%) | catalogued as rs536742820; called by muse, mutect2, varscan2
- TBX5 | c.982+20G>T | Intron (SNP) | VAF 39/234 reads (17%) | catalogued as COSV59864205; called by muse, mutect2, varscan2
- TCP10L3 | n.100G>C | RNA (SNP) | VAF 53/295 reads (18%) | called by muse, mutect2, varscan2
- TMC6 | c.271+28G>T | Intron (SNP) | VAF 37/181 reads (20%) | called by muse, mutect2, varscan2
- TPSG1 | c.47-33C>A | Intron (SNP) | VAF 47/299 reads (16%) | called by muse, mutect2, varscan2
- TRAPPC9 | chr8:140458341 C>G | 5'Flank (SNP) | VAF 75/289 reads (26%) | called by muse, mutect2, varscan2
- TUBB8P7 | n.894+207C>T | Intron (SNP) | VAF 54/318 reads (17%) | called by muse, mutect2, varscan2
- URM1 | c.237+154G>T | Intron (SNP) | VAF 31/208 reads (15%) | called by muse, mutect2, varscan2
- URM1 | c.237+155G>T | Intron (SNP) | VAF 32/207 reads (15%) | called by muse, mutect2, varscan2
- YBX1 | c.167-283G>T | Intron (SNP) | VAF 27/227 reads (12%) | called by muse, mutect2, varscan2
- ZFHX3 | c.-533+34G>A | Intron (SNP) | VAF 61/267 reads (23%) | catalogued as rs375198244; called by muse, mutect2, varscan2
- ZNF12 | c.-474G>T | 5'UTR (SNP) | VAF 50/163 reads (31%) | catalogued as rs1036199835; called by muse, mutect2, varscan2
- ZNF141 | c.226+13808A>T | Intron (SNP) | VAF 27/98 reads (28%) | called by muse, mutect2, varscan2
- ZNF658B | n.833G>T | RNA (SNP) | VAF 75/427 reads (18%) | called by muse, mutect2, varscan2
